Somatic mutation profile of tumor specimen TARGET-10-PATBTX-09A (aliquot TARGET-10-PATBTX-09A-01D) from TARGET case TARGET-10-PATBTX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,152 days).
Specimen TARGET-10-PATBTX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bc3a1d8-66e2-463f-9fca-6311549d605d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATBTX-10A (Blood Derived Normal), aliquot TARGET-10-PATBTX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c24ec47-4e54-4d68-9253-360a04a6c3e2

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Frame Shift Ins 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG5 | c.127A>C p.S43R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58348496; called by muse, mutect2, varscan2
- CYP2C9 | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53249693; called by muse, mutect2, varscan2
- EML2 | c.1643G>A p.R548K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.718); catalogued as COSV55600431; called by muse, mutect2, varscan2
- FGD3 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV61597996; called by muse, mutect2, varscan2
- GRIN2B | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as rs1295510907, COSV74204691; called by muse, mutect2, varscan2
- PTEN | c.697_698insAGCCGCCGCTTTTGGAGGGC p.R233Qfs*30 | Frame Shift Ins (INS) | VAF 10/51 reads (20%) | catalogued as COSV64288717, COSV64289856, COSV64298421, COSV64299115, COSV64306382, COSV64307526, COSV99058011, COSV99058016, COSV99058020; called by mutect2, pindel, varscan2
- SNED1 | c.3286G>A p.A1096T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs138901734, COSV60025758; called by muse, varscan2
- SORBS1 | c.281G>A p.R94Q (on ENST00000361941 / NM_001034954.2; = p.R62Q on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs756153047, COSV53359192; called by muse, mutect2
- USP7 | c.340dup p.S114Kfs*11 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | called by mutect2, varscan2
- APBA1 | c.1113C>T p.P371= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs1460472929, COSV55233726; called by muse, mutect2, varscan2
- KIAA1671 | c.6C>T p.A2= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- RAB17 | c.276C>T p.N92= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs373239912; called by muse, mutect2, varscan2
- XDH | c.3528C>T p.R1176= | Silent (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- CHST5 | c.-1210C>A | 5'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- NAGPA | c.921-260G>T | Intron (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
